Somatic mutation profile of tumor specimen C3N-01481-01 (aliquot CPT0105810005) from CPTAC case C3N-01481, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 73.5 years (26,853 days).
Specimen C3N-01481-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Head & Neck; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b21082d0-ffb1-42e6-b189-a3bb8f32c5e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01481-31 (Blood Derived Normal), aliquot CPT0110020002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/851c1f21-4210-460a-a05c-c29df31f39d7

The open-access MAF lists 228 somatic variants for this specimen: 138 protein-altering or splice-affecting, 83 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 129, Silent 83, Nonsense Mutation 5, Intron 4, 5'Flank 2, Frame Shift Ins 2, Translation Start Site 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>G p.V640G (on ENST00000288602 / NM_001374244.1; = p.V600G on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/298 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/298 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.3251C>T p.S1084F | Missense Mutation (SNP) | VAF 69/292 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52199773; called by muse, mutect2, varscan2
- ACVRL1 | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 84/459 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM023319, CM050995, COSV66360180; called by muse, mutect2, varscan2
- ADPRHL1 | c.4370C>T p.T1457M | Missense Mutation (SNP) | VAF 101/522 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.895); catalogued as rs368619068; called by muse, mutect2, varscan2
- AHCY | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 76/427 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); catalogued as COSV54153036; called by muse, mutect2, varscan2
- APOB | c.10894A>T p.R3632* | Nonsense Mutation (SNP) | VAF 111/521 reads (21%) | catalogued as COSV51956582; called by muse, mutect2, varscan2
- CAMTA1 | c.1970C>T p.S657F | Missense Mutation (SNP) | VAF 99/536 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.556); catalogued as rs1347747219; called by muse, mutect2, varscan2
- CNBD2 | c.1619C>T p.T540M (on ENST00000373973 / NM_001365709.1; = p.T536M on NM_080834.4) | Missense Mutation (SNP) | VAF 86/457 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.197); catalogued as rs571562114, COSV62586286; called by muse, mutect2, varscan2
- CNGA2 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 77/311 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as rs139084709, COSV61703101; called by muse, mutect2, varscan2
- CNTNAP3 | c.2356C>T p.R786C | Missense Mutation (SNP) | VAF 48/268 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.586); catalogued as rs762454175, COSV99905395; called by muse, mutect2, varscan2
- CSMD1 | c.9379G>A p.G3127S (on ENST00000520002; = p.G3126S on NM_033225.6) | Missense Mutation (SNP) | VAF 79/472 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59289246, COSV59380853; called by muse, mutect2, varscan2
- DHX57 | c.2167C>T p.R723C | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs762534427, COSV54883718; called by muse, mutect2, varscan2
- DNAH14 | c.9700G>A p.E3234K (on ENST00000445597; = p.E4242K on NM_001367479.1) | Missense Mutation (SNP) | VAF 54/304 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.875); catalogued as COSV59900784; called by muse, mutect2, varscan2
- EHMT2 | c.1198C>T p.L400F | Missense Mutation (SNP) | VAF 159/537 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs757222987; called by muse, mutect2, varscan2
- FAM222A | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 106/535 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.085); catalogued as rs1326543924; called by muse, mutect2, varscan2
- FBLIM1 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 118/592 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs923782709, COSV60029047; called by muse, mutect2, varscan2
- FCAMR | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as rs375632066, COSV61367607; called by muse, mutect2, varscan2
- FMN2 | c.4094C>T p.S1365L | Missense Mutation (SNP) | VAF 50/260 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60438252; called by muse, mutect2, varscan2
- GDF3 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 46/309 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867390778, COSV61712125; called by muse, mutect2, varscan2
- GRIN2A | c.3397C>T p.P1133S | Missense Mutation (SNP) | VAF 94/589 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV58029865; called by muse, mutect2, varscan2
- GRIN2B | c.4333G>A p.D1445N | Missense Mutation (SNP) | VAF 103/554 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV74205372; called by muse, mutect2, varscan2
- GRM4 | c.120G>A p.M40I | Missense Mutation (SNP) | VAF 212/663 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs757920195, COSV100946875; called by muse, mutect2, varscan2
- H1-6 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 86/627 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs1292688890; called by muse, mutect2, varscan2
- HYDIN | c.1412G>A p.G471E | Missense Mutation (SNP) | VAF 113/304 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1478956863, COSV99862812; called by muse, mutect2, varscan2
- IGF2R | c.6242C>T p.P2081L | Missense Mutation (SNP) | VAF 64/344 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.046); catalogued as rs151080511, COSV100807483; called by muse, mutect2, varscan2
- IGFALS | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 104/539 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs1028585073, COSV51906548; called by muse, mutect2, varscan2
- ITGA2B | c.1808C>T p.S603F | Missense Mutation (SNP) | VAF 59/413 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52234878; called by muse, mutect2, varscan2
- ITGB6 | c.2294C>T p.S765F | Missense Mutation (SNP) | VAF 45/254 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51790831; called by muse, mutect2, varscan2
- KCNB2 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 83/599 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as rs756745272, COSV73049820; called by muse, mutect2, varscan2
- KHNYN | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 100/515 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs760232261, COSV52159120; called by muse, mutect2, varscan2
- KIAA1671 | c.1930C>T p.R644C | Missense Mutation (SNP) | VAF 136/600 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1206581264; called by muse, mutect2, varscan2
- KIF2B | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 114/522 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as rs1229299890, COSV52127464; called by muse, mutect2, varscan2
- KLHL13 | c.1211G>A p.G404E | Missense Mutation (SNP) | VAF 88/420 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs867961131, COSV53250888; called by muse, mutect2
- KLHL30 | c.1571G>A p.G524D | Missense Mutation (SNP) | VAF 120/576 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs1163568624; called by muse, mutect2, varscan2
- KMT2D | c.11102C>T p.P3701L | Missense Mutation (SNP) | VAF 69/438 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.888); catalogued as CD122096; called by muse, mutect2, varscan2
- MACF1 | c.8639G>A p.G2880D | Missense Mutation (SNP) | VAF 63/301 reads (21%) | catalogued as rs769035859; called by muse, mutect2, varscan2
- MED13 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 56/265 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV67262865; called by muse, mutect2, varscan2
- MFSD11 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 79/362 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs369294744; called by muse, mutect2, varscan2
- MICB | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 165/491 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as rs771839061; called by muse, mutect2, varscan2
- MUC16 | c.18481C>T p.P6161S | Missense Mutation (SNP) | VAF 106/480 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.01); catalogued as COSV67481950; called by muse, mutect2, varscan2
- MUC17 | c.6071C>T p.S2024L | Missense Mutation (SNP) | VAF 93/419 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV100071358; called by muse, mutect2, varscan2
- MYBPC1 | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 46/272 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.415); catalogued as COSV62252541; called by muse, mutect2, varscan2
- MYH6 | c.2335C>T p.R779W | Missense Mutation (SNP) | VAF 59/379 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs182951502, COSV62449457; called by muse, mutect2, varscan2
- MYO18B | c.5734G>A p.D1912N | Missense Mutation (SNP) | VAF 65/337 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.173); catalogued as rs766609930; called by muse, mutect2, varscan2
- MYOCD | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 62/337 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV100590227, COSV100591043; called by muse, mutect2, varscan2
- NCOA6 | c.5384C>T p.P1795L | Missense Mutation (SNP) | VAF 80/376 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.518); catalogued as COSV62862098; called by muse, mutect2, varscan2
- OR4K1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 51/448 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53458821; called by muse, mutect2, varscan2
- OR4K1 | c.927G>A p.W309* | Nonsense Mutation (SNP) | VAF 34/284 reads (12%) | catalogued as COSV53458913, COSV53460428; called by muse, mutect2
- OR51B5 | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 63/302 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100332485, COSV56175061; called by muse, mutect2, varscan2
- OR5H1 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 88/517 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV63402174; called by muse, mutect2, varscan2
- OR8D4 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 92/472 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs1262570745, COSV58431502; called by muse, mutect2, varscan2
- OR8J3 | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 52/327 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as rs267602994, COSV56880060; called by muse, mutect2, varscan2
- OTOF | c.3613C>T p.R1205C (on ENST00000272371 / NM_194248.3; = p.R458C on NM_004802.4) | Missense Mutation (SNP) | VAF 82/488 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as rs747452208, COSV55499991, COSV99717869; called by muse, mutect2, varscan2
- PAPPA2 | c.4292C>T p.A1431V | Missense Mutation (SNP) | VAF 61/333 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as COSV62802811; called by muse, mutect2, varscan2
- PCDHB8 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 158/1317 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs782113084, COSV99176960; called by muse, mutect2, varscan2
- PRSS58 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 53/288 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as COSV101616180; called by muse, mutect2, varscan2
- RBM42 | c.52G>A p.V18I | Missense Mutation (SNP) | VAF 91/410 reads (22%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.043); catalogued as COSV52549385; called by muse, mutect2, varscan2
- RHO | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 51/276 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV56214600; called by muse, mutect2, varscan2
- RPTOR | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 56/351 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV60805951; called by muse, mutect2, varscan2
- SCN3A | c.3652C>T p.L1218F | Missense Mutation (SNP) | VAF 66/356 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51811475; called by muse, mutect2, varscan2
- SLC22A6 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 53/358 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.025); catalogued as rs377471841; called by muse, mutect2, varscan2
- SLC25A21 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780255591, COSV58723097; called by muse, mutect2, varscan2
- SLFN12L | c.1099C>T p.L367F (on ENST00000260908 / NM_001363830.1; = p.L385F on NM_001195790.1) | Missense Mutation (SNP) | VAF 51/264 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV53469848; called by muse, mutect2, varscan2
- SNCAIP | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 57/250 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs766744242; called by muse, mutect2, varscan2
- SYT1 | c.1202C>A p.P401H | Missense Mutation (SNP) | VAF 114/476 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs759645770; called by muse, mutect2, varscan2
- TBX5 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 69/394 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.189); catalogued as CM971437; called by muse, mutect2, varscan2
- TCF20 | c.3934C>T p.P1312S | Missense Mutation (SNP) | VAF 117/605 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV100166915; called by muse, mutect2, varscan2
- TET3 | c.1597C>T p.H533Y | Missense Mutation (SNP) | VAF 94/566 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs756490941; called by muse, mutect2, varscan2
- TF | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 67/346 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV99396547; called by muse, mutect2, varscan2
- THSD7B | c.3071C>T p.S1024F | Missense Mutation (SNP) | VAF 92/486 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55654422; called by muse, mutect2, varscan2
- TLE1 | c.1684C>T p.P562S | Missense Mutation (SNP) | VAF 97/448 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as rs373236831, COSV64723641; called by muse, mutect2, varscan2
- TMEM161A | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 107/541 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779335342; called by muse, mutect2, varscan2
- TMEM168 | c.588G>T p.M196I | Missense Mutation (SNP) | VAF 56/358 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV57179384; called by muse, mutect2, varscan2
- TPTE | c.368C>T p.P123L (on ENST00000618007 / NM_199261.4; = p.P105L on NM_199259.4) | Missense Mutation (SNP) | VAF 64/742 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.218); catalogued as rs537044433; called by muse, mutect2
- WDR87 | c.4742G>A p.R1581Q | Missense Mutation (SNP) | VAF 82/512 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.047); catalogued as rs746570223, COSV58192802; called by muse, mutect2
- YEATS2 | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 77/321 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as rs545279252; called by muse, mutect2, varscan2
- ZMIZ1 | c.544C>T p.L182F | Missense Mutation (SNP) | VAF 83/299 reads (28%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.143); catalogued as COSV100566305; called by muse, mutect2, varscan2
- ZNF676 | c.1591C>T p.H531Y (on ENST00000650058; = p.H499Y on NM_001001411.3) | Missense Mutation (SNP) | VAF 65/363 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV68094309; called by muse, mutect2
- ACAN | c.7207G>A p.E2403K (on ENST00000560601 / NM_001369268.1; = p.E2327K on NM_001135.3) | Missense Mutation (SNP) | VAF 52/338 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- ADAM2 | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 61/293 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- AK9 | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 74/470 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- AMT | c.31C>A p.L11M | Missense Mutation (SNP) | VAF 72/384 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); called by mutect2, varscan2
- ARHGEF5 | c.2476C>T p.P826S | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- ARSF | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 51/255 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- BRD4 | c.3076C>T p.Q1026* | Nonsense Mutation (SNP) | VAF 56/283 reads (20%) | called by muse, mutect2, varscan2
- CCDC188 | c.491del p.L164Rfs*10 | Frame Shift Del (DEL) | VAF 36/270 reads (13%) | called by mutect2, pindel, varscan2
- CCDC61 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 82/494 reads (17%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CDH4 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 70/443 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CEP170B | c.2486C>G p.P829R (on ENST00000453495; = p.P758R on NM_015005.3) | Missense Mutation (SNP) | VAF 132/582 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- COL6A5 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 41/264 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSN2 | c.661C>T p.H221Y | Missense Mutation (SNP) | VAF 57/316 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DENND4A | c.1505dup p.N502Kfs*13 | Frame Shift Ins (INS) | VAF 55/275 reads (20%) | called by mutect2, pindel, varscan2
- DKKL1 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 97/592 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.022); called by muse, mutect2
- EFEMP2 | c.1286G>A p.S429N | Missense Mutation (SNP) | VAF 83/532 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ETV1 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 69/317 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- F13B | c.1111C>T p.H371Y | Missense Mutation (SNP) | VAF 55/304 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- FAM47A | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 134/560 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- FANCB | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 93/374 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HDAC9 | c.2470G>A p.G824R | Missense Mutation (SNP) | VAF 71/300 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ICAM5 | c.2501C>T p.P834L | Missense Mutation (SNP) | VAF 62/345 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- IGLL1 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 95/442 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- IGSF11 | c.1204C>T p.H402Y (on ENST00000393775 / NM_001015887.3; = p.H401Y on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/424 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- IMPDH2 | c.151C>A p.L51M | Missense Mutation (SNP) | VAF 47/257 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- IQUB | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 39/156 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LAMA5 | c.10286C>T p.S3429F | Missense Mutation (SNP) | VAF 84/454 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LBP | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 85/383 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.624); called by muse, varscan2
- LRRC70 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 53/262 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MUC12 | c.8737G>A p.E2913K (on ENST00000379442; = p.E2770K on NM_001164462.1) | Missense Mutation (SNP) | VAF 62/2300 reads (3%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.958); called by muse, mutect2
- MUC16 | c.15184G>A p.D5062N | Missense Mutation (SNP) | VAF 69/362 reads (19%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- MYH8 | c.4579C>T p.H1527Y | Missense Mutation (SNP) | VAF 54/313 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- NCOA6 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 100/512 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, varscan2
- NLRP13 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 94/446 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOTO | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 79/372 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NRIP1 | c.2302A>T p.T768S | Missense Mutation (SNP) | VAF 84/382 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NYNRIN | c.2752C>T p.P918S | Missense Mutation (SNP) | VAF 54/362 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- OR6B3 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 83/487 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- PAAF1 | c.928A>T p.S310C | Missense Mutation (SNP) | VAF 32/269 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- PCF11 | c.69G>C p.Q23H | Missense Mutation (SNP) | VAF 71/433 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PHF21B | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 115/555 reads (21%) | called by muse, mutect2, varscan2
- PLA2G3 | c.1396G>A p.D466N | Missense Mutation (SNP) | VAF 90/500 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- PNPLA7 | c.2030C>T p.S677F | Missense Mutation (SNP) | VAF 74/358 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PTEN | c.491dup p.V166Sfs*14 | Frame Shift Ins (INS) | VAF 61/231 reads (26%) | called by mutect2, pindel, varscan2
- RGS7 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 59/416 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- RPL26 | c.313G>C p.V105L | Missense Mutation (SNP) | VAF 50/270 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RTL10 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 103/559 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- RTN2 | c.1133C>T p.S378F | Missense Mutation (SNP) | VAF 87/502 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SCN1A | c.970C>T p.H324Y | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC22A3 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 67/365 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- SLC46A2 | c.1288T>C p.Y430H | Missense Mutation (SNP) | VAF 85/488 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TEK | c.2462G>A p.W821* | Nonsense Mutation (SNP) | VAF 85/415 reads (20%) | called by muse, mutect2, varscan2
- TK1 | c.679A>G p.I227V | Missense Mutation (SNP) | VAF 76/366 reads (21%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSPAN8 | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 49/240 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- VWDE | c.3902C>T p.P1301L | Missense Mutation (SNP) | VAF 48/282 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- ZBTB8B | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 85/548 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- ZMAT4 | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 93/467 reads (20%) | SIFT tolerated (0.92); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF10 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 62/380 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- ZNF605 | c.1579C>T p.H527Y | Missense Mutation (SNP) | VAF 83/491 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCB11 | c.2724C>T p.F908= | Silent (SNP) | VAF 104/656 reads (16%) | catalogued as rs760637527; called by muse, mutect2, varscan2
- ACVRL1 | c.852C>T p.S284= | Silent (SNP) | VAF 114/568 reads (20%) | called by muse, mutect2, varscan2
- AP1M2 | c.873G>A p.V291= | Silent (SNP) | VAF 62/339 reads (18%) | called by muse, mutect2, varscan2
- AP3B1 | c.1341C>T p.V447= | Silent (SNP) | VAF 67/393 reads (17%) | catalogued as rs778991987; called by muse, mutect2, varscan2
- BCL2L12 | c.51C>T p.F17= | Silent (SNP) | VAF 70/385 reads (18%) | catalogued as rs267605591, COSV55862539; called by muse, mutect2, varscan2
- BTBD8 | c.540C>T p.S180= | Silent (SNP) | VAF 37/200 reads (19%) | called by muse, mutect2, varscan2
- CAMSAP3 | c.1614G>A p.S538= | Silent (SNP) | VAF 97/548 reads (18%) | catalogued as COSV50334686; called by muse, mutect2, varscan2
- CCDC168 | c.6252G>A p.G2084= | Silent (SNP) | VAF 67/422 reads (16%) | called by muse, mutect2, varscan2
- CDH12 | c.117T>C p.V39= | Silent (SNP) | VAF 73/472 reads (15%) | called by muse, mutect2, varscan2
- CDKL5 | c.987C>T p.A329= | Silent (SNP) | VAF 65/326 reads (20%) | catalogued as rs142665931; ClinVar: likely benign; called by muse, mutect2, varscan2
- CNTNAP3 | c.3654C>T p.P1218= | Silent (SNP) | VAF 67/767 reads (9%) | called by muse, mutect2
- COL6A3 | c.438C>T p.I146= | Silent (SNP) | VAF 77/454 reads (17%) | catalogued as rs781449958; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.3513C>T p.I1171= | Silent (SNP) | VAF 74/387 reads (19%) | catalogued as rs755097067, COSV100650183, COSV62028722; called by muse, mutect2, varscan2
- DEUP1 | c.189G>A p.Q63= | Silent (SNP) | VAF 62/306 reads (20%) | called by muse, mutect2, varscan2
- DMBT1 | c.1794C>T p.S598= | Silent (SNP) | VAF 81/455 reads (18%) | called by muse, mutect2, varscan2
- DOCK10 | c.4137C>T p.F1379= | Silent (SNP) | VAF 43/233 reads (18%) | called by muse, mutect2, varscan2
- ECM1 | c.636C>T p.F212= | Silent (SNP) | VAF 85/447 reads (19%) | catalogued as COSV100681604; called by muse, mutect2, varscan2
- EEF2 | c.1785C>T p.S595= | Silent (SNP) | VAF 76/457 reads (17%) | catalogued as rs777167717; called by muse, mutect2, varscan2
- EFEMP2 | c.1287C>T p.S429= | Silent (SNP) | VAF 81/527 reads (15%) | called by muse, mutect2, varscan2
- EHD2 | c.810C>T p.L270= | Silent (SNP) | VAF 145/676 reads (21%) | called by muse, mutect2, varscan2
- ELAPOR2 | c.1818C>T p.A606= (on ENST00000450689 / NM_001142749.3; = p.A439= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 92/480 reads (19%) | catalogued as COSV51889578; called by muse, mutect2, varscan2
- ERICH3 | c.2796G>A p.E932= | Silent (SNP) | VAF 80/497 reads (16%) | catalogued as rs1250190199, COSV58616410; called by muse, mutect2, varscan2
- EXOC3L2 | c.486G>A p.K162= | Silent (SNP) | VAF 63/414 reads (15%) | called by muse, mutect2, varscan2
- EYS | c.3981G>A p.L1327= | Silent (SNP) | VAF 80/450 reads (18%) | called by muse, mutect2, varscan2
- FAM13C | c.903G>A p.R301= | Silent (SNP) | VAF 62/296 reads (21%) | catalogued as COSV53243654; called by muse, mutect2, varscan2
- FHOD3 | c.2448C>T p.V816= (on ENST00000359247 / NM_001281739.3; = p.V833= on NM_025135.5) | Silent (SNP) | VAF 78/460 reads (17%) | called by muse, mutect2, varscan2
- FLG2 | c.4560C>T p.H1520= | Silent (SNP) | VAF 97/651 reads (15%) | called by muse, mutect2, varscan2
- FLT1 | c.3102C>T p.N1034= | Silent (SNP) | VAF 84/337 reads (25%) | catalogued as rs377691426; called by muse, mutect2, varscan2
- GUCY1A2 | c.1458G>A p.E486= | Silent (SNP) | VAF 77/413 reads (19%) | catalogued as COSV56486955, COSV56500726; called by muse, mutect2, varscan2
- HYDIN | c.7194G>A p.E2398= | Silent (SNP) | VAF 25/214 reads (12%) | called by muse, mutect2, varscan2
- IFT140 | c.3963C>T p.S1321= | Silent (SNP) | VAF 121/611 reads (20%) | catalogued as rs371103494, COSV100794097; called by muse, mutect2, varscan2
- IPO13 | c.2388C>T p.L796= | Silent (SNP) | VAF 48/408 reads (12%) | catalogued as COSV64893562; called by muse, mutect2, varscan2
- ITGAX | c.1573C>T p.L525= | Silent (SNP) | VAF 106/548 reads (19%) | called by muse, mutect2
- KCNV2 | c.12G>A p.Q4= | Silent (SNP) | VAF 63/327 reads (19%) | called by muse, mutect2, varscan2
- KIF4B | c.2328G>A p.Q776= | Silent (SNP) | VAF 112/562 reads (20%) | catalogued as rs1410578844, COSV70528344; called by muse, mutect2, varscan2
- MACC1 | c.738C>T p.F246= | Silent (SNP) | VAF 62/353 reads (18%) | called by muse, mutect2, varscan2
- MAGEA10 | c.774G>A p.G258= | Silent (SNP) | VAF 121/498 reads (24%) | catalogued as rs1176582023, COSV54885326; called by muse, mutect2, varscan2
- MAGEB17 | c.711C>T p.F237= | Silent (SNP) | VAF 104/398 reads (26%) | called by muse, mutect2, varscan2
- MICAL1 | c.447C>T p.T149= | Silent (SNP) | VAF 49/284 reads (17%) | catalogued as rs1241967712; called by muse, mutect2, varscan2
- MIIP | c.216C>T p.S72= | Silent (SNP) | VAF 98/526 reads (19%) | catalogued as rs139363608; called by muse, mutect2, varscan2
- MPP7 | c.420C>T p.I140= | Silent (SNP) | VAF 29/131 reads (22%) | catalogued as rs267602464, COSV61731856; called by muse, mutect2, varscan2
- MTPAP | c.597A>G p.L199= | Silent (SNP) | VAF 63/263 reads (24%) | called by muse, mutect2, varscan2
- MUC16 | c.42618C>T p.F14206= | Silent (SNP) | VAF 90/431 reads (21%) | called by muse, mutect2, varscan2
- MUC16 | c.24396C>A p.T8132= | Silent (SNP) | VAF 112/565 reads (20%) | called by muse, mutect2, varscan2
- MUC16 | c.2053C>T p.L685= | Silent (SNP) | VAF 86/382 reads (23%) | catalogued as rs1486622536, COSV101201421; called by muse, mutect2, varscan2
- MYH2 | c.2223C>T p.F741= | Silent (SNP) | VAF 53/274 reads (19%) | catalogued as rs749480408; called by muse, mutect2, varscan2
- MYH3 | c.1437C>T p.I479= | Silent (SNP) | VAF 85/453 reads (19%) | called by muse, mutect2, varscan2
- MYH4 | c.759C>T p.I253= | Silent (SNP) | VAF 63/307 reads (21%) | catalogued as COSV55126794; called by muse, mutect2, varscan2
- MYO5B | c.2949G>A p.E983= | Silent (SNP) | VAF 94/495 reads (19%) | called by muse, mutect2, varscan2
- OR10AC1 | c.813C>T p.L271= | Silent (SNP) | VAF 64/482 reads (13%) | called by muse, mutect2
- OR3A2 | c.117C>T p.L39= | Silent (SNP) | VAF 38/288 reads (13%) | called by muse, mutect2, varscan2
- OR52K2 | c.903C>T p.I301= | Silent (SNP) | VAF 68/350 reads (19%) | catalogued as rs1183045273, COSV57834631; called by muse, varscan2
- OR9G1 | c.858C>T p.L286= | Silent (SNP) | VAF 74/644 reads (11%) | called by muse, mutect2, varscan2
- PARP9 | c.1779C>T p.L593= | Silent (SNP) | VAF 90/440 reads (20%) | catalogued as COSV64451514; called by muse, mutect2, varscan2
- PEAR1 | c.27T>A p.L9= | Silent (SNP) | VAF 68/379 reads (18%) | catalogued as COSV52774138; called by muse, mutect2, varscan2
- PGD | c.1395C>T p.I465= | Silent (SNP) | VAF 82/386 reads (21%) | catalogued as COSV54621496; called by muse, mutect2, varscan2
- PPP3R2 | c.486C>T p.I162= | Silent (SNP) | VAF 67/327 reads (20%) | called by muse, mutect2, varscan2
- PPP6R1 | c.432G>A p.R144= | Silent (SNP) | VAF 70/361 reads (19%) | catalogued as rs1286442895; called by muse, mutect2, varscan2
- PPY | c.114G>A p.G38= | Silent (SNP) | VAF 104/539 reads (19%) | called by muse, mutect2, varscan2
- PSG5 | c.327C>T p.I109= | Silent (SNP) | VAF 68/408 reads (17%) | catalogued as COSV61653990; called by muse, mutect2, varscan2
- PTPRE | c.504C>T p.I168= | Silent (SNP) | VAF 29/155 reads (19%) | called by muse, mutect2, varscan2
- RAB8A | c.396C>T p.S132= | Silent (SNP) | VAF 59/345 reads (17%) | catalogued as rs1401701186; called by muse, mutect2, varscan2
- SCAF4 | c.1998C>T p.V666= | Silent (SNP) | VAF 65/459 reads (14%) | catalogued as rs1489161834; called by muse, mutect2, varscan2
- SCN11A | c.549C>T p.F183= | Silent (SNP) | VAF 56/323 reads (17%) | catalogued as COSV56567084; called by muse, mutect2, varscan2
- SCN3A | c.1254G>A p.L418= | Silent (SNP) | VAF 55/332 reads (17%) | catalogued as COSV51801358; called by muse, mutect2, varscan2
- SLC22A3 | c.639C>T p.F213= | Silent (SNP) | VAF 64/397 reads (16%) | called by muse, mutect2, varscan2
- SLC22A6 | c.879G>A p.R293= | Silent (SNP) | VAF 51/356 reads (14%) | catalogued as COSV64560444; called by muse, mutect2, varscan2
- SLC26A9 | c.1140C>T p.S380= | Silent (SNP) | VAF 55/300 reads (18%) | catalogued as COSV100536547; called by muse, mutect2, varscan2
- SLC2A5 | c.582C>T p.I194= | Silent (SNP) | VAF 57/312 reads (18%) | called by muse, mutect2, varscan2
- SLC45A3 | c.825C>T p.F275= | Silent (SNP) | VAF 87/489 reads (18%) | catalogued as rs143103785; called by muse, mutect2, varscan2
- SLC46A2 | c.1287C>T p.I429= | Silent (SNP) | VAF 85/485 reads (18%) | catalogued as rs202214849; called by muse, mutect2, varscan2
- SYT10 | c.837G>A p.R279= | Silent (SNP) | VAF 86/357 reads (24%) | catalogued as rs760778883, COSV57336955; called by muse, mutect2, varscan2
- TBXT | c.1307G>A p.*436= | Silent (SNP) | VAF 55/320 reads (17%) | called by muse, mutect2, varscan2
- TEX51 | c.498G>A p.V166= (on ENST00000643416; = p.V142= on NM_001322244.2) | Silent (SNP) | VAF 78/419 reads (19%) | called by muse, mutect2, varscan2
- TFPI2 | c.45C>T p.F15= | Silent (SNP) | VAF 90/484 reads (19%) | catalogued as rs1278347582, COSV99746679; called by muse, mutect2, varscan2
- TM6SF1 | c.127C>T p.L43= | Silent (SNP) | VAF 78/419 reads (19%) | catalogued as rs975108128, COSV51943598; called by muse, mutect2, varscan2
- TMIE | c.216C>T p.I72= | Silent (SNP) | VAF 36/283 reads (13%) | catalogued as rs762792362; called by muse, mutect2, varscan2
- TRPC4 | c.1029C>T p.F343= | Silent (SNP) | VAF 78/460 reads (17%) | called by muse, mutect2, varscan2
- VPS35L | c.1608T>C p.D536= | Silent (SNP) | VAF 54/339 reads (16%) | called by muse, mutect2, varscan2
- VWF | c.2661G>A p.G887= | Silent (SNP) | VAF 69/455 reads (15%) | called by muse, mutect2, varscan2
- WDFY4 | c.1371C>T p.F457= | Silent (SNP) | VAF 97/408 reads (24%) | catalogued as rs767767458, COSV57428372; called by muse, mutect2, varscan2
- ZAN | c.6147G>A p.G2049= | Silent (SNP) | VAF 96/414 reads (23%) | called by muse, mutect2, varscan2
- ZNF226 | c.885T>A p.L295= | Silent (SNP) | VAF 103/454 reads (23%) | called by muse, mutect2, varscan2
- BNC1 | c.99+1392G>A | Intron (SNP) | VAF 69/301 reads (23%) | called by muse, mutect2, varscan2
- C2orf16 | chr2:27575828 T>G | 5'Flank (SNP) | VAF 71/368 reads (19%) | called by muse, mutect2, varscan2
- EP400 | c.1335+1669C>T | Intron (SNP) | VAF 72/319 reads (23%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+3251G>A | Intron (SNP) | VAF 103/600 reads (17%) | called by muse, mutect2, varscan2
- PLEKHG4B | chr5:139656 C>T | 5'Flank (SNP) | VAF 52/321 reads (16%) | called by muse, mutect2, varscan2
- PSTK | c.*122T>C | 3'UTR (SNP) | VAF 66/322 reads (20%) | catalogued as rs541164934; called by muse, mutect2, varscan2
- PYM1 | c.38-10864C>T | Intron (SNP) | VAF 74/344 reads (22%) | called by muse, mutect2, varscan2
